Gene-level copy-number profile of tumor specimen ALCH-B40S-TTP1-A from ALCHEMIST case ALCH-B40S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,101 days).
Specimen ALCH-B40S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 493baec4-eaff-42b9-8821-7f44d3098a3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,281 have no estimate.
https://portal.gdc.cancer.gov/files/c4654b70-4360-4a61-8ff2-5db01295c517

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 180; copy number 1: 5,993; copy number 2: 35,287; copy number 3: 13,185; copy number 4: 2,272; copy number 5: 807; copy number 6: 228; copy number 7: 145; copy number 8: 111; copy number 9: 77; copy number 10: 6; copy number 11: 22; copy number 12: 1; copy number 13: 6; copy number 14: 3; copy number 15: 4; copy number 17: 4; copy number 19: 6; copy number 20: 1; copy number 29: 3; copy number 34: 1.

Homozygous deletions (total copy number 0; autosomes only): 167 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–1): AL512383.1.
- chr1:5,478,736–5,494,674, 2 genes: Z98259.3, Z98259.1.
- chr1:9,588,911–9,614,877, 1 gene: TMEM201.
- chr2:388,412–578,145, 5 genes: AC105393.2, AC105393.1, LINC01874, LINC01875, AC093326.1.
- chr2:1,341,044–1,625,419, 6 genes (within-gene range 0–1): AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1.
- chr2:120,542,905–120,558,119, 2 genes: AC073257.2, AC073257.1.
- chr2:217,799,588–218,033,982, 3 genes: TNS1, MIR6809, TNS1-AS1.
- chr2:237,257,091–237,601,614, 10 genes: AC112715.1, COL6A3, AC112721.1, AC112721.2, MLPH, MIR6811, RNU6-1140P, PRLH, RAB17, AC104667.2.
- chr2:238,244,044–238,300,620, 3 genes (within-gene range 0–2): PER2, AC012485.3, AC012485.2.
- chr2:238,554,541–240,030,456, 21 genes (within-gene range 0–1): LINC01937, AC113618.2, AC113618.1, AC145625.1, TWIST2, LINC01940, HDAC4, MIR4440, MIR4441, AC017028.1, AC017028.2, MIR4269, MIR2467, HDAC4-AS1, AC079612.1, AC079612.2, AC093802.2, AC093802.1, NDUFA10, MIR4786, OR6B2.
- chr2:240,109,102–240,144,562, 3 genes: OR5S1P, COPS9, OTOS.
- chr2:240,906,330–240,993,311, 3 genes (within-gene range 0–1): CROCC2, UICLM, AC104809.1.
- chr4:8,436,140–8,493,531, 2 genes (within-gene range 0–1): TRMT44, AC105345.2.
- chr4:9,076,949–9,141,608, 2 genes: AC073648.7, ENPP7P10.
- chr4:151,887,543–151,943,933, 3 genes: AC112242.1, AC097375.2, AC097375.1.
- chr4:189,659,605–189,704,490, 2 genes: LINC01262, AF250324.1.
- chr8:7,200,756–7,290,402, 6 genes: AF228730.1, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P.
- chr8:7,332,387–7,338,707, 2 genes (within-gene range 0–1): USP17L1, USP17L4.
- chr9:134,641,803–134,844,843, 3 genes (within-gene range 0–1): COL5A1, COL5A1-AS1, AL645768.1.
- chr10:48,878,022–48,935,213, 3 genes (within-gene range 0–1): AC035139.1, AC060234.3, LRRC18.
- chr10:49,364,181–49,396,016, 1 gene: DRGX.
- chr10:123,913,574–123,931,597, 1 gene (within-gene range 0–1): AC068058.1.
- chr10:124,004,304–124,093,598, 2 genes: AL683842.1, CHST15.
- chr10:128,958,772–128,960,062, 1 gene: AL355537.1.
- chr10:129,467,190–129,973,053, 9 genes: MGMT, AL355531.1, AL157832.2, AL157832.1, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3.
- chr10:130,213,488–130,483,193, 1 gene (within-gene range 0–1): LINC02646.
- chr10:131,092,391–131,311,721, 2 genes: TCERG1L, TCERG1L-AS1.
- chr10:132,397,168–132,417,859, 1 gene: PWWP2B.
- chr11:112,787,304–112,795,854, 1 gene: AP003100.1.
- chr14:104,450,979–104,605,647, 4 genes: CEND1P1, TMEM179, C14orf180, BX927359.1.
- chr16:50,666,300–50,681,353, 1 gene (within-gene range 0–2): SNX20.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr16:86,636,328–86,668,923, 2 genes: AC009108.2, AC009154.1.
- chr18:78,908,629–78,928,494, 3 genes: AC091027.2, AC091027.1, AC091027.3.
- chr18:79,340,258–79,354,567, 2 genes (within-gene range 0–1): AC023090.1, AC023090.2.
- chr20:62,596,732–62,776,996, 12 genes: BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659.
- chr20:63,034,217–63,053,863, 2 genes (within-gene range 0–1): LINC00029, LINC01056.
- chr21:41,882,205–41,954,018, 2 genes: AP001619.3, C2CD2.
- chr21:42,199,689–42,297,244, 2 genes: ABCG1, RNA5SP492.
- chr21:42,346,357–42,396,091, 3 genes: TFF2, TFF1, TMPRSS3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,422 genes in 117 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,036,321–151,249,536, 14 genes, copy number 5: BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A.
- chr1:155,127,876–155,227,422, 14 genes, copy number 5: EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1.
- chr2:25,697,076–26,028,612, 9 genes, copy number 5: Y_RNA, ASXL2, TPM3P7, PTGES3P2, AC064847.1, NDUFB4P4, KIF3C, UQCRHP2, TRMT112P6.
- chr2:27,325,849–27,582,721, 16 genes, copy number 5: GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16.
- chr2:38,666,081–38,975,454, 14 genes, copy number 5: GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1.
- chr2:177,344,443–178,402,893, 18 genes, copy number 5–6 (within-gene range 4–6): H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6.
- chr2:182,909,115–183,495,501, 10 genes, copy number 5–6: NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1.
- chr3:169,083,499–171,054,973, 50 genes, copy number 5–9: MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2.
- chr3:175,473,919–184,135,238, 157 genes, copy number 5–17 (within-gene range 3–17) (broad region; genes not listed).
- chr3:185,162,871–185,980,872, 15 genes, copy number 5: EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P.
- chr3:195,836,193–196,832,647, 50 genes, copy number 5: LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1, AC024937.3, AC024937.2, TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P.
- chr4:54,229,280–55,032,071, 11 genes, copy number 11–19 (within-gene range 3–19): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P.
- chr6:42,928,287–43,075,095, 16 genes, copy number 5 (within-gene range 4–5): AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2.
- chr7:6,329,411–6,624,290, 12 genes, copy number 5: FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853.
- chr7:74,231,499–74,760,692, 9 genes, copy number 5–7: RFC2, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15.
- chr7:100,367,530–100,797,797, 28 genes, copy number 5 (within-gene range 4–5): PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, NYAP1, AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B, GNB2, GIGYF1, POP7, EPO, ZAN.
- chr7:142,332,182–142,492,673, 23 genes, copy number 5: TRBV7-1, TRBV4-2, TRBV8-1, TRBV5-2, TRBV6-4, TRBV7-3, TRBV8-2, TRBV5-3, TRBV9, TRBV10-1, TRBV11-1, TRBV12-1, TRBV10-2, TRBV11-2, TRBV12-2, TRBV6-5, TRBV7-4, TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6.
- chr8:144,373,101–144,529,132, 22 genes, copy number 5–6: ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, LRRC14, LRRC24, C8orf82.
- chr9:4,553,386–4,782,078, 9 genes, copy number 5 (within-gene range 3–5): SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1.
- chr9:4,944,670–6,507,054, 44 genes, copy number 5: HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1.
- chr11:46,936,689–47,191,542, 8 genes, copy number 5: C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1.
- chr11:69,294,151–70,436,584, 35 genes, copy number 5–9: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:41,188,320–42,238,349, 11 genes, copy number 5–8: PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2.
- chr12:55,870,048–56,103,505, 16 genes, copy number 5 (within-gene range 4–5): OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3.
- chr12:123,233,436–123,441,852, 11 genes, copy number 5–6 (within-gene range 3–6): C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2.
- chr14:34,485,979–34,630,160, 9 genes, copy number 5: RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3.
- chr15:21,405,401–22,095,857, 35 genes, copy number 7–8 (within-gene range 2–15): POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr16:62,187,540–63,703,665, 13 genes, copy number 5 (within-gene range 5–6): RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1.
- chr18:20,946,906–21,600,884, 10 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1.
- chr18:25,953,216–27,247,188, 27 genes, copy number 5–6: AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908.
- chr18:46,667,821–49,461,347, 54 genes, copy number 5–9 (within-gene range 3–10): ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, ELOA3D, ELOA3C, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1, SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1.
- chr19:14,380,501–15,498,956, 58 genes, copy number 6–9: ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2.
- chr19:17,390,509–17,448,668, 8 genes, copy number 5 (within-gene range 4–5): CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221.
- chr19:18,418,864–19,252,233, 41 genes, copy number 5–8: SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD, TMEM59L, RN7SL155P, KLHL26, CRTC1, COMP, UPF1, GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49, HOMER3, HOMER3-AS1, RN7SL70P, SUGP2, ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P.
- chr19:20,972,262–27,646,483, 141 genes, copy number 5–9 (broad region; genes not listed).
- chr19:36,003,307–39,111,493, 141 genes, copy number 5–7 (broad region; genes not listed).
- chr19:39,264,382–39,428,415, 13 genes, copy number 6: IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2.
- chr19:40,191,426–40,576,464, 22 genes, copy number 11–12: MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4.
- chr20:36,870,099–37,179,588, 9 genes, copy number 5 (within-gene range 3–5): RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3, AL136172.1, MROH8, AL031659.1.
- chr22:18,501,794–18,638,405, 11 genes, copy number 6–34: FAM247B, GGTLC3, Metazoa_SRP, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2.

Autosomal genes at a single copy (total copy number 1): 5,481. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
